Somatic mutation profile of tumor specimen TCGA-IR-A3LI-01A (aliquot TCGA-IR-A3LI-01A-11D-A20U-09) from TCGA case TCGA-IR-A3LI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 48.6 years (17,741 days).
Specimen TCGA-IR-A3LI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 409aaced-1a56-4df6-b9ee-edc9424920eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LI-10A (Blood Derived Normal), aliquot TCGA-IR-A3LI-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f63e76-cc31-4d38-86c7-36a2200a8344

The open-access MAF lists 406 somatic variants for this specimen: 276 protein-altering or splice-affecting, 122 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 242, Silent 122, Nonsense Mutation 25, Intron 4, Splice Region 4, Splice Site 3, 3'Flank 2, In Frame Del 1, 5'Flank 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 41/85 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.898G>A p.E300K (on ENST00000326724 / NM_001080395.3; = p.E197K on NM_004920.2) | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV58685953; called by muse, mutect2, varscan2
- ABCA1 | c.2861C>T p.S954L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1005990127, COSV66064579; called by muse, mutect2, varscan2
- ACBD5 | c.1126G>A p.E376K (on ENST00000375888 / NM_001352568.1; = p.E367K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV101022586; called by muse, mutect2
- ACSS1 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60218556; called by muse, mutect2, varscan2
- ACTC1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV51757816; called by muse, mutect2, varscan2
- ADCK5 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as COSV58232728; called by muse, mutect2, varscan2
- ADCY2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1247552881; called by muse, mutect2, varscan2
- ADGRF5 | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99346078; called by muse, mutect2
- ADGRV1 | c.15653G>A p.G5218E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67980751; called by muse, mutect2, varscan2
- AFAP1L1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV57044364; called by muse, mutect2, varscan2
- AHNAK2 | c.8715G>C p.K2905N | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV60910667; called by muse, mutect2, varscan2
- AKNA | c.2844C>T p.I948= | Splice Region (SNP) | VAF 38/90 reads (42%) | catalogued as COSV56311589, COSV56313679; called by muse, mutect2, varscan2
- ALMS1 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV52505287; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3869C>A p.S1290Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51842737, COSV99784714; called by muse, mutect2, varscan2
- ANKIB1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV56059675, COSV56062947; called by muse, mutect2, varscan2
- AP1G1 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 14/19 reads (74%) | catalogued as COSV55486734; called by muse, mutect2, varscan2
- AP5M1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55104781; called by muse, mutect2, varscan2
- ARHGEF18 | c.2038C>T p.P680S (on ENST00000359920 / NM_001130955.2; = p.P576S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60468101; called by muse, mutect2, varscan2
- ARHGEF5 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs761138536, COSV50208392; called by muse, mutect2, varscan2
- ASMTL | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101187846; called by muse, mutect2, varscan2
- ASPHD1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1367597474, COSV58098029; called by muse, mutect2, varscan2
- ASPM | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV54126676; called by muse, mutect2, varscan2
- ATP11C | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100558335, COSV59559427; called by muse, mutect2
- ATP8B4 | c.3431C>G p.S1144C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52711458; called by muse, mutect2, varscan2
- BCL2L13 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV58225199; called by muse, mutect2, varscan2
- BCS1L | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs779504946, COSV55306428; called by muse, varscan2
- BMI1 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); catalogued as COSV64958810; called by muse, mutect2, varscan2
- BTN2A1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57002527; called by muse, mutect2, varscan2
- C11orf68 | c.466C>G p.Q156E (on ENST00000530188; = p.Q197E on NM_031450.4) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.374); catalogued as COSV56988172; called by muse, mutect2, varscan2
- C14orf39 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58780220, COSV58783087; called by muse, mutect2, varscan2
- CASK | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as COSV59363639; called by muse, mutect2
- CCDC151 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as rs759215057, COSV52950710; called by muse, mutect2, varscan2
- CCDC6 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1465093020, COSV54055534; called by muse, mutect2, varscan2
- CCNA2 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV54665259; called by muse, mutect2, varscan2
- CCNL1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55816640; called by muse, mutect2, varscan2
- CDC42BPB | c.5078C>G p.S1693C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1485309676, COSV54486292; called by muse, varscan2
- CDH23 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV54927789; called by muse, mutect2, varscan2
- CDK10 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs376294252; called by muse, mutect2, varscan2
- CELSR2 | c.8161G>A p.D2721N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs150439556; called by muse, mutect2, varscan2
- CENPF | c.4520C>G p.S1507C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV65273425; called by muse, mutect2, varscan2
- CEP112 | c.2458-1G>A p.X820_splice (on ENST00000392769 / NM_001353127.1; = p.X76_splice on NM_001037325.3) | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV58062671; called by muse, mutect2, varscan2
- CFAP58 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57211614; called by muse, mutect2, varscan2
- CHAF1A | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs749929809, COSV56670982; called by muse, mutect2, varscan2
- CHD5 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs1230512841, COSV52407586; called by muse, mutect2, varscan2
- CIAO3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376966046; called by muse, mutect2, varscan2
- CLCN1 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV58368384; called by muse, mutect2, varscan2
- CLEC12A | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs766054849, COSV100429585, COSV58560778; called by muse, mutect2, varscan2
- CMPK2 | c.727T>C p.C243R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.196); catalogued as COSV56774197; called by muse, mutect2, varscan2
- CMYA5 | c.9811G>A p.D3271N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs777014375, COSV71404585; called by muse, mutect2, varscan2
- COPS4 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52314047; called by muse, mutect2, varscan2
- CSMD3 | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV52130537; called by muse, mutect2, varscan2
- CX3CL1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV50055553, COSV99136376; called by muse, mutect2, varscan2
- CZIB | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99598253; called by muse, mutect2
- DAGLA | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57194832; called by muse, mutect2, varscan2
- DENND4A | c.3526G>A p.E1176K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV71265426; called by muse, mutect2, varscan2
- DHX29 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV52417178; called by muse, mutect2, varscan2
- DNAH10 | c.7774G>A p.E2592K (on ENST00000409039; = p.E2531K on NM_207437.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1267563266, COSV68990021; called by muse, mutect2, varscan2
- DNAH2 | c.4330C>G p.L1444V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV66717673; called by muse, mutect2, varscan2
- DNAH5 | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54211935, COSV54245362; called by muse, mutect2, varscan2
- DNAJC2 | c.1428-1G>A p.X476_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV50785697; called by muse, mutect2, varscan2
- DNAJC5B | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52536400; called by muse, mutect2, varscan2
- DNAL4 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53308629; called by muse, mutect2, varscan2
- DNMT3L | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV54266651; called by muse, mutect2
- DRC7 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as COSV61053695; called by muse, mutect2, varscan2
- DUS3L | c.1528A>T p.M510L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57831413; called by muse, mutect2, varscan2
- DZIP1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100713993, COSV61264574; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs763136855, COSV62567064; called by muse, mutect2, varscan2
- EIF3D | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.063); catalogued as rs968706921, COSV53399200; called by muse, mutect2, varscan2
- EIF3I | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV59084130; called by muse, mutect2, varscan2
- EIF4G2 | c.1938T>G p.F646L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.724); catalogued as COSV101150984; called by muse, mutect2, varscan2
- ELMO1 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs867300194, COSV60298876; called by muse, mutect2, varscan2
- ELOA | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as COSV69309633; called by muse, mutect2, varscan2
- ERAP1 | c.2690C>G p.S897C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1232807490, COSV57086042; called by muse, mutect2, varscan2
- ERCC6L2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV56629145; called by muse, mutect2, varscan2
- FAM160B2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1563598994, COSV57157475; called by muse, mutect2, varscan2
- FAM217A | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV51159245, COSV51160378; called by muse, mutect2, varscan2
- FBXL20 | c.1000C>G p.H334D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99234510; called by muse, mutect2
- FOSB | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62278494; called by muse, mutect2, varscan2
- GBP3 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV52517769; called by muse, mutect2, varscan2
- GGT1 | c.1206C>G p.L402= | Splice Region (SNP) | VAF 59/123 reads (48%) | catalogued as COSV50638710; called by muse, mutect2, varscan2
- GLUD1 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV53277882; called by muse, mutect2, varscan2
- GNRH2 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs761550854, COSV55661454; called by muse, mutect2, varscan2
- GOLGA4 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as COSV62709752; called by muse, mutect2, varscan2
- GPR45 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1352198171, COSV51523131; called by muse, mutect2, varscan2
- GPSM3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100900832; called by muse, mutect2
- GRIK5 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as rs778282413, COSV53476244; called by muse, mutect2, varscan2
- GRIN1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100160538, COSV59294188; called by muse, mutect2, varscan2
- GRIN2D | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV54377585; called by muse, mutect2, varscan2
- H4C9 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62889659; called by muse, mutect2, varscan2
- HARBI1 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); catalogued as COSV56318233; called by muse, mutect2, varscan2
- HECA | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs931389617, COSV62768725; called by muse, mutect2, varscan2
- HIVEP2 | c.3929C>G p.S1310C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV50006977, COSV50060737; called by muse, mutect2, varscan2
- HRC | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV53255616; called by muse, mutect2, varscan2
- HRC | c.1200G>C p.K400N | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV53255627, COSV53257599; called by muse, mutect2, varscan2
- HUWE1 | c.8617G>A p.D2873N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV53338600; called by muse, mutect2, varscan2
- IGHV3-23 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.056); catalogued as rs892965558; called by muse, mutect2, varscan2
- ING4 | c.419C>A p.A140D (on ENST00000396807 / NM_001127582.2; = p.A139D on NM_016162.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV58554382; called by muse, varscan2
- INKA2 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV61877370; called by muse, mutect2, varscan2
- INTU | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.342); catalogued as rs1560827869, COSV56538694; called by muse, mutect2, varscan2
- IQGAP3 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100752237; called by muse, mutect2
- IQSEC2 | c.2824C>T p.R942W (on ENST00000642864 / NM_001111125.3; = p.R737W on NM_015075.2) | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV64724168; called by muse, mutect2, varscan2
- ITGA1 | c.2684G>A p.R895K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV50877530; called by muse, mutect2, varscan2
- ITGA11 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1427538732, COSV59875979; called by muse, mutect2, varscan2
- ITGA11 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772135483, COSV59875986; called by muse, mutect2, varscan2
- KCNA10 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV63904382; called by muse, mutect2, varscan2
- KCNA5 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV52904473; called by muse, mutect2, varscan2
- KCTD3 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV52065061; called by muse, mutect2, varscan2
- KIAA0100 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55931568; called by muse, mutect2, varscan2
- KLHDC7A | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV68769262; called by muse, varscan2
- KLHDC7A | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs927726106, COSV68769268; called by muse, varscan2
- KRT15 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1445365258, COSV54178622; called by muse, mutect2, varscan2
- KRT36 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60202791; called by muse, mutect2, varscan2
- KRT76 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV60119525; called by muse, mutect2, varscan2
- LAMA2 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.243); catalogued as rs776531251, COSV70342383; called by muse, mutect2, varscan2
- LAMA5 | c.5603G>C p.G1868A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53355431; called by muse, mutect2
- LAMC1 | c.3728C>T p.S1243L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV51134693; called by muse, mutect2, varscan2
- LAMTOR4 | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100385570, COSV57585615; called by muse, mutect2
- LARP4B | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as COSV60220512; called by muse, mutect2, varscan2
- LASP1 | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV58802959; called by mutect2, varscan2
- LCE1E | c.49_60del p.T17_C20del | In Frame Del (DEL) | VAF 26/94 reads (28%) | catalogued as rs774512501; called by mutect2, varscan2
- LCOR | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53714975; called by muse, mutect2
- LILRB2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV100079508; called by muse, mutect2, varscan2
- LIMK2 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53223198; called by muse, mutect2, varscan2
- LY86 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as COSV57911311; called by muse, mutect2, varscan2
- LYST | c.5168G>C p.R1723T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV67704571; called by muse, mutect2, varscan2
- MAGEA4 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as rs747218857, COSV52340660; called by muse, mutect2, varscan2
- MAP1A | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55807120; called by muse, mutect2, varscan2
- MAP1A | c.1379C>G p.S460C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV55807131, COSV55807443; called by muse, mutect2, varscan2
- MAP1A | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449810482, COSV55807140; called by muse, mutect2, varscan2
- MAPK15 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62027691; called by muse, mutect2, varscan2
- MAPKAPK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54314972; called by muse, mutect2, varscan2
- MAS1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV53120784; called by muse, mutect2, varscan2
- MB21D2 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as COSV66662341; called by muse, mutect2, varscan2
- MCF2L2 | c.3238G>A p.E1080K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1560327153, COSV100193370; called by muse, mutect2
- MED12 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV61334846; called by muse, mutect2, varscan2
- MEF2D | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV61727384; called by muse, mutect2, varscan2
- MELTF | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1318341033, COSV56379870; called by muse, mutect2, varscan2
- MICALL2 | c.2625G>A p.M875I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1378953281, COSV52514759; called by muse, mutect2, varscan2
- MINK1 | c.1970G>A p.W657* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV61789157; called by muse, mutect2, varscan2
- MKI67 | c.6268G>A p.E2090K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV64073249; called by muse, mutect2, varscan2
- MMP21 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100523750; called by muse, mutect2
- MMS22L | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51517886; called by muse, mutect2, varscan2
- MPHOSPH9 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV56617714, COSV56619637; called by muse, mutect2, varscan2
- MPP1 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as COSV65728080; called by muse, mutect2, varscan2
- MPP7 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV100517674; called by muse, mutect2, varscan2
- MRPL15 | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52637170; called by muse, mutect2
- MSX1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66947103; called by muse, mutect2, varscan2
- MUC16 | c.33686C>G p.S11229* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101200574; called by muse, mutect2
- MYH15 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.909); catalogued as COSV56306269; called by muse, mutect2, varscan2
- MYO6 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV64117581; called by muse, mutect2, varscan2
- NBAS | c.7018G>T p.E2340* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV55715668; called by muse, mutect2
- NCOA6 | c.5867C>T p.S1956F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as COSV62862101; called by muse, mutect2, varscan2
- NDUFS3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV55453990; called by mutect2, varscan2
- NELFA | c.839G>A p.R280Q (on ENST00000542778; = p.R269Q on NM_005663.5) | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs745686118, COSV56388317; called by muse, mutect2, varscan2
- NLRC3 | c.2801G>C p.G934A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57088783; called by muse, mutect2, varscan2
- NLRP14 | c.2965C>T p.Q989* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as rs773885092, COSV55065118; called by muse, mutect2, varscan2
- NOL3 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50456766; called by muse, mutect2, varscan2
- NOTCH2 | c.6892C>T p.R2298W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1270274564, COSV56685860; called by muse, mutect2, varscan2
- NPC1L1 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs756628304, COSV56923389; called by muse, mutect2, varscan2
- NUTF2 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99534517; called by muse, mutect2, varscan2
- NXPH3 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60871927; called by muse, mutect2, varscan2
- OBSCN | c.18430G>T p.D6144Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52753179; called by muse, mutect2, varscan2
- OR13C9 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV52241116; called by muse, mutect2, varscan2
- OR6N1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58647694; called by muse, mutect2, varscan2
- PAK2 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.296); catalogued as COSV59082324, COSV59085199; called by muse, mutect2, varscan2
- PARD6B | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763915421, COSV100859931, COSV65404197; called by muse, mutect2, varscan2
- PBX1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV61532653; called by muse, mutect2, varscan2
- PCED1B | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV71394998; called by muse, mutect2, varscan2
- PCSK2 | c.1035G>C p.E345D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52728423; called by muse, mutect2, varscan2
- PDZRN3 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1430486296, COSV55193859; called by muse, mutect2, varscan2
- PHF13 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV50010689; called by muse, mutect2, varscan2
- PKD2L1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754844314, COSV58394617; called by muse, mutect2, varscan2
- PLEKHH1 | c.2298C>G p.I766M | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV61281456; called by muse, mutect2, varscan2
- PLPPR4 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64564843; called by muse, mutect2, varscan2
- POLR3B | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV57276885; called by muse, mutect2, varscan2
- POTEH | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs768451586, COSV58881205; called by muse, mutect2, varscan2
- PPFIA3 | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.946); catalogued as COSV53255609; called by muse, mutect2, varscan2
- PPP1R10 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64738771; called by muse, mutect2
- PPP4R3B | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV55402752; called by muse, mutect2, varscan2
- PREPL | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.708); catalogued as COSV53215677; called by muse, mutect2, varscan2
- PRPF18 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60724827, COSV60724844; called by muse, mutect2, varscan2
- PSMD6 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs757884032, COSV55759181; called by muse, mutect2, varscan2
- PTTG2 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV54715834; called by muse, mutect2, varscan2
- PUM1 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV99928572; called by muse, mutect2, varscan2
- PXDNL | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV62482337, COSV62486113; called by muse, mutect2, varscan2
- RALGPS2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.13); catalogued as COSV61336126; called by muse, mutect2, varscan2
- RAPGEF4 | c.1939C>G p.L647V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51381521, COSV99910133; called by muse, mutect2, varscan2
- RBL1 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60328918; called by muse, mutect2, varscan2
- RBM5 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV61736950; called by muse, mutect2, varscan2
- RBM6 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV56480702; called by muse, mutect2, varscan2
- RFX4 | c.1011C>G p.I337M (on ENST00000392842 / NM_213594.3; = p.I243M on NM_032491.6) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57573606; called by muse, mutect2, varscan2
- RNASEL | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV62376411; called by muse, mutect2, varscan2
- RNF17 | c.4310C>G p.S1437C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55036182; called by muse, mutect2, varscan2
- RPGR | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58833286; called by muse, mutect2, varscan2
- RTL1 | c.2857G>A p.D953N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.159); catalogued as COSV66016542; called by muse, mutect2, varscan2
- SCLY | c.1157G>A p.R386Q (on ENST00000651534; = p.R378Q on NM_016510.7) | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs150718596; called by muse, mutect2, varscan2
- SCN11A | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100182629, COSV56567488; called by muse, mutect2, varscan2
- SCN3A | c.3929G>C p.R1310T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51804845; called by muse, mutect2, varscan2
- SDE2 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs765185264, COSV55250518, COSV55253040; called by muse, mutect2, varscan2
- SEMG2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1325207189, COSV65647145; called by mutect2, varscan2
- SENP5 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60206563; called by muse, mutect2, varscan2
- SEPTIN9 | c.451G>A p.E151K (on ENST00000427177 / NM_001113491.2; = p.E133K on NM_006640.4) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as COSV61202971; called by muse, mutect2, varscan2
- SERPIND1 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV53137832, COSV53139148; called by muse, mutect2, varscan2
- SGO2 | c.2674G>T p.D892Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV63414478, COSV63417123; called by muse, mutect2, varscan2
- SIGLEC9 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV51583155, COSV51585753; called by muse, mutect2, varscan2
- SIX5 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV52176379; called by muse, varscan2
- SIX5 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52176393; called by muse, mutect2, varscan2
- SLC12A1 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.49); catalogued as rs769849492, COSV66793012; called by muse, varscan2
- SLC19A3 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV51451843; called by muse, mutect2, varscan2
- SLC25A41 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV51190654; called by muse, mutect2, varscan2
- SLC2A12 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51598632; called by muse, mutect2
- SLC9A2 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1356071403; called by muse, mutect2, varscan2
- SNX15 | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV57246212; called by muse, mutect2, varscan2
- SON | c.5257G>C p.E1753Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV51653423; called by muse, mutect2, varscan2
- SPAG17 | c.5824G>C p.E1942Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV60455116; called by muse, mutect2, varscan2
- SPATS2 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100423343, COSV58917407; called by muse, mutect2
- SPATS2 | c.1480C>G p.Q494E | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV58917418, COSV58920421; called by muse, mutect2, varscan2
- SPSB2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV51290048; called by muse, mutect2, varscan2
- SRGAP1 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV61895569; called by muse, mutect2, varscan2
- SRPK2 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61959918; called by muse, mutect2, varscan2
- SUN2 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.11); catalogued as rs1376134458, COSV53302655; called by muse, mutect2, varscan2
- SYT14 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV55050622; called by muse, mutect2, varscan2
- TAF1L | c.4489G>A p.D1497N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1218636028, COSV54259512; called by muse, mutect2, varscan2
- TAF1L | c.3823G>C p.E1275Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV54259521; called by muse, mutect2, varscan2
- TAF1L | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs756132965, COSV54259523; called by muse, mutect2, varscan2
- TAP2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV66498508; called by muse, mutect2
- TBC1D17 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV55577700; called by muse, mutect2, varscan2
- TCF20 | c.5398C>T p.R1800W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1040465334, COSV59489273; called by muse, mutect2, varscan2
- TDRD1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs1483030218, COSV52588824; called by muse, mutect2, varscan2
- TENM1 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV64427547; called by muse, mutect2, varscan2
- TEX14 | c.3136G>T p.E1046* (on ENST00000240361 / NM_001201457.2; = p.E1040* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53613569; called by muse, mutect2, varscan2
- TEX14 | c.1429G>A p.D477N (on ENST00000240361 / NM_001201457.2; = p.D471N on NM_031272.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53613589; called by muse, mutect2, varscan2
- TFCP2 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56931921; called by muse, mutect2, varscan2
- TFPI2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs753875527, COSV55990226; called by muse, mutect2, varscan2
- TMEM42 | c.339G>A p.S113= | Splice Region (SNP) | VAF 27/66 reads (41%) | catalogued as rs769658359, COSV56643672; called by muse, mutect2, varscan2
- TOPBP1 | c.4323G>T p.L1441F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53433785, COSV53441997; called by muse, mutect2, varscan2
- TOPBP1 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV53433807; called by muse, mutect2, varscan2
- TRAPPC11 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764158202, COSV58215337; called by muse, mutect2, varscan2
- TTN | c.40099G>T p.E13367* (on ENST00000591111; = p.E5943* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV59943060; called by muse, mutect2, varscan2
- TTN | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | PolyPhen benign (0.175); catalogued as COSV59943139; called by muse, mutect2, varscan2
- UBAP2L | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV55169885; called by muse, mutect2, varscan2
- UBAP2L | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55169923; called by muse, mutect2, varscan2
- UGCG | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65335495; called by muse, mutect2, varscan2
- USHBP1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1027556121; called by muse, mutect2
- UTP14A | c.384C>T p.I128= | Splice Region (SNP) | VAF 3/50 reads (6%) | catalogued as COSV64087793; called by muse, mutect2
- WDR62 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54332943; called by muse, mutect2, varscan2
- WNK1 | c.3607G>A p.D1203N (on ENST00000315939 / NM_018979.4; = p.D956N on NM_014823.3) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV60027923; called by muse, mutect2, varscan2
- YES1 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1354676545, COSV58848775; called by muse, mutect2, varscan2
- YIPF2 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53403011; called by muse, mutect2
- YTHDC2 | c.4273G>C p.E1425Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.074); catalogued as COSV50737800; called by muse, mutect2
- ZBTB40 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV65144836; called by muse, mutect2, varscan2
- ZCCHC12 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV59571169; called by muse, mutect2, varscan2
- ZDHHC14 | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV63069589; called by muse, mutect2, varscan2
- ZDHHC8 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV57709385; called by muse, mutect2, varscan2
- ZFX | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as COSV58446784; called by muse, mutect2, varscan2
- ZNF292 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.085); catalogued as COSV60536918; called by muse, mutect2, varscan2
- ZNF292 | c.3084G>C p.L1028F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.708); catalogued as COSV60536926; called by muse, mutect2, varscan2
- ZNF366 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59214358; called by muse, mutect2, varscan2
- ZNF436 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs779583975, COSV58358240; called by muse, mutect2, varscan2
- ZNF467 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1381552478, COSV57371946; called by muse, mutect2, varscan2
- ZNF506 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV71354290; called by muse, mutect2, varscan2
- ZNF564 | c.1186C>G p.Q396E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV59434581; called by muse, mutect2, varscan2
- ZNF564 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs555349242, COSV59434587; called by muse, mutect2, varscan2
- ZNF570 | c.1269C>G p.F423L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57578448; called by muse, mutect2, varscan2
- ZNF761 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV61887843; called by muse, mutect2, varscan2
- ZNF878 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV72155893, COSV72155948; called by muse, mutect2, varscan2
- ZP2 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as COSV54812920; called by muse, mutect2, varscan2
- ZRSR2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as rs777454064, COSV57063979; called by muse, mutect2, varscan2
- GOLGA6L9 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PARP4 | c.2651C>G p.S884C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOX17 | c.363_365dup p.E122dup | In Frame Ins (INS) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- TMCO4 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2
- VCX3A | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 29/217 reads (13%) | called by muse, mutect2, varscan2
- VPS72 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); called by muse, varscan2
- ACVR1C | c.723G>A p.T241= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs753140064, COSV54644626; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1659C>G p.P553= | Silent (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- ADCY3 | c.795G>A p.K265= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV53165363; called by muse, mutect2, varscan2
- ADCY5 | c.3216C>T p.V1072= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV59195643, COSV59197291; called by muse, mutect2, varscan2
- ADCY8 | c.2829G>C p.L943= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV53900617, COSV53914784; called by muse, mutect2, varscan2
- AMOTL2 | c.1503G>A p.E501= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV51438239; called by muse, mutect2, varscan2
- ANO4 | c.1182C>T p.I394= (on ENST00000392977 / NM_001286615.2; = p.I359= on NM_178826.4) | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV54585854; called by muse, mutect2, varscan2
- APC2 | c.1902G>C p.L634= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV52016795; called by muse, mutect2, varscan2
- ARHGEF10 | c.21C>T p.L7= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100035992, COSV50644019; called by muse, mutect2, varscan2
- ARHGEF12 | c.279C>T p.F93= | Silent (SNP) | VAF 36/43 reads (84%) | catalogued as rs370997007; called by muse, mutect2, varscan2
- ARRDC5 | c.813C>T p.F271= (on ENST00000381781; = p.F257= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV67787839; called by muse, mutect2, varscan2
- ASB15 | c.279G>A p.E93= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs750289666, COSV51924577, COSV51926186; called by muse, mutect2, varscan2
- BAZ1B | c.265C>T p.L89= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV59989592; called by muse, mutect2, varscan2
- BCO1 | c.454C>T p.L152= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV50728564; called by muse, mutect2, varscan2
- CEP95 | c.2283G>A p.Q761= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV73608841; called by muse, mutect2
- CLCNKA | c.1779C>T p.I593= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs149572981; called by muse, mutect2, varscan2
- CNIH3 | c.279G>T p.L93= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV55273692; called by muse, mutect2, varscan2
- CNNM4 | c.2327G>A p.*776= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV65660418; called by muse, mutect2, varscan2
- CORO7 | c.1989C>T p.V663= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV52028720; called by muse, mutect2, varscan2
- CRYBB1 | c.522C>T p.L174= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99316122; called by muse, mutect2
- CRYGD | c.135C>G p.L45= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV52204930; called by muse, mutect2, varscan2
- CSF2RB | c.1992G>A p.G664= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV53256349; called by muse, mutect2, varscan2
- CSMD1 | c.540C>T p.H180= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs368684088; called by muse, mutect2, varscan2
- CSPP1 | c.2173C>T p.L725= (on ENST00000676605; = p.L684= on NM_024790.6) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV51580548, COSV51581619; called by muse, mutect2, varscan2
- CTBP1 | c.471G>A p.Q157= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV52072753; called by muse, mutect2, varscan2
- DAZAP1 | c.798C>T p.I266= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs200390993, COSV99245282, COSV99245397; called by muse, mutect2, varscan2
- DCST1 | c.1800G>A p.K600= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV55057451; called by muse, mutect2, varscan2
- DENND4B | c.3435C>T p.F1145= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV63407839; called by muse, mutect2, varscan2
- DGCR6L | c.639G>A p.Q213= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV50618831; called by muse, mutect2, varscan2
- DOP1A | c.3210C>T p.L1070= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV52708132; called by muse, mutect2, varscan2
- DSTYK | c.2235G>A p.L745= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV65685763; called by muse, mutect2, varscan2
- ENO2 | c.615C>A p.T205= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV50387256; called by muse, varscan2
- ENTPD8 | c.1047C>T p.F349= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs778280388, COSV58160921; called by muse, mutect2, varscan2
- ENTPD8 | c.663C>A p.I221= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100395655; called by muse, mutect2, varscan2
- ERCC3 | c.798G>A p.Q266= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99573518; called by muse, mutect2, varscan2
- FOXM1 | c.1764C>G p.L588= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV61205531; called by muse, mutect2, varscan2
- FRYL | c.4668G>A p.L1556= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99977575; called by muse, mutect2, varscan2
- FSCB | c.2053C>T p.L685= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as rs1198030627, COSV61217224; called by muse, varscan2
- GTF2IRD1 | c.2205G>A p.K735= (on ENST00000265755 / NM_016328.3; = p.K720= on NM_005685.4) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99735088; called by muse, mutect2, varscan2
- H1-5 | c.549G>A p.P183= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100137999; called by muse, varscan2
- HECTD4 | c.4740G>A p.L1580= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV66388689; called by muse, mutect2, varscan2
- HECTD4 | c.4077A>G p.L1359= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV61178238; called by muse, mutect2, varscan2
- HEPH | c.3279G>A p.V1093= (on ENST00000343002; = p.V826= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100295198, COSV57960846; called by muse, mutect2, varscan2
- HTR4 | c.1113C>T p.F371= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV58791168; called by muse, mutect2, varscan2
- IMP4 | c.759G>A p.L253= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV52091384; called by muse, mutect2, varscan2
- IQCE | c.96G>A p.R32= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV58077109, COSV58080131; called by muse, mutect2, varscan2
- KRT6B | c.1434C>T p.G478= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs753121763, COSV52882580, COSV52885375; called by muse, mutect2, varscan2
- KRT6B | c.1164C>T p.I388= | Silent (SNP) | VAF 78/148 reads (53%) | catalogued as COSV52882585; called by muse, mutect2, varscan2
- KYNU | c.1398G>A p.*466= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1484654815, COSV51580824; called by muse, mutect2, varscan2
- LGI4 | c.42G>A p.A14= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs760793071, COSV59532949; called by muse, mutect2, varscan2
- LRRC24 | c.1437C>G p.L479= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV52878366; called by muse, varscan2
- MAPT | c.1623G>A p.T541= (on ENST00000262410 / NM_001377265.1; = p.T149= on NM_005910.5) | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs139748238; ClinVar: likely benign; called by muse, mutect2, varscan2
- MDN1 | c.12465G>A p.E4155= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV65531615; called by muse, mutect2
- MEX3D | c.789C>T p.A263= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs972218247, COSV66311853; called by muse, mutect2, varscan2
- MMS19 | c.318C>T p.I106= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59134303; called by muse, varscan2
- MROH7 | c.2238C>T p.I746= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV59869304; called by muse, mutect2, varscan2
- MRPL9 | c.552G>A p.L184= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV58617626; called by muse, mutect2, varscan2
- MTCH1 | c.336G>A p.P112= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs755488075, COSV65320040; called by muse, mutect2, varscan2
- MTHFS | c.237C>T p.F79= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- MTO1 | c.705G>A p.L235= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV64773310; called by muse, mutect2, varscan2
- MUC16 | c.33133C>T p.L11045= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs889386890, COSV101201997, COSV67490431; called by muse, mutect2
- MYO7A | c.2811C>G p.V937= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV68683968; called by muse, mutect2, varscan2
- NFKB1 | c.1521G>A p.Q507= (on ENST00000394820 / NM_001382627.1; = p.Q508= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs747985052, COSV56955169; called by muse, mutect2, varscan2
- NUMB | c.315C>T p.L105= (on ENST00000355058; = p.L94= on NM_003744.5) | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV61828480; called by muse, mutect2, varscan2
- OR11H12 | c.135C>T p.L45= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV73543479, COSV73543533, COSV73543857; called by muse, mutect2, varscan2
- OR1S1 | c.381C>G p.L127= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs765053703, COSV58706307, COSV58706461; called by muse, mutect2
- OR51D1 | c.30C>T p.I10= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV100712387, COSV62913995; called by muse, mutect2, varscan2
- OR5L2 | c.307T>C p.L103= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV65723633; called by muse, mutect2, varscan2
- OR6N1 | c.913C>T p.L305= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV58647677; called by muse, varscan2
- OR6N1 | c.864C>T p.F288= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV58647685; called by muse, varscan2
- OR6N1 | c.87C>T p.L29= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58647698; called by muse, mutect2, varscan2
- PCDH15 | c.4752G>A p.L1584= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV57276437; called by muse, mutect2, varscan2
- PCGF3 | c.174G>A p.V58= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV62858612; called by muse, mutect2, varscan2
- PCSK6 | c.1866G>A p.L622= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- PECR | c.408C>T p.F136= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54733804; called by muse, mutect2, varscan2
- PGAP4 | c.450G>A p.V150= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV66387318; called by muse, mutect2, varscan2
- PLEKHG1 | c.498C>T p.I166= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV62045926; called by muse, mutect2, varscan2
- PPP6R3 | c.273G>A p.Q91= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV55722970; called by mutect2, varscan2
- RAB11FIP1 | c.2730C>G p.L910= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV54758910; called by muse, mutect2, varscan2
- RORA | c.579G>A p.L193= (on ENST00000335670 / NM_134261.3; = p.L218= on NM_002943.3) | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV55036725; called by muse, mutect2, varscan2
- SEMA6A | c.888C>A p.L296= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV57308289; called by muse, mutect2, varscan2
- SERPINA3 | c.265C>T p.L89= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67585508; called by muse, mutect2, varscan2
- SERPINA5 | c.276G>A p.L92= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs771690010, COSV61573740; called by muse, mutect2, varscan2
- SHCBP1L | c.1731G>A p.L577= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV62353831; called by muse, mutect2, varscan2
- SIGLEC5 | c.1536G>A p.L512= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs147945480; called by muse, mutect2, varscan2
- SIX5 | c.2082G>A p.L694= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as COSV52176373; called by muse, varscan2
- SLC15A4 | c.723C>T p.L241= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1172381357, COSV57160788; called by muse, mutect2, varscan2
- SLC18A1 | c.1410C>T p.V470= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV52347255; called by muse, mutect2, varscan2
- SLC25A32 | c.741C>T p.V247= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV52567107; called by muse, mutect2, varscan2
- SLC44A2 | c.2120G>A p.*707= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1488613842, COSV59835684; called by muse, mutect2, varscan2
- SLFNL1 | c.15G>A p.K5= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV57234243; called by muse, mutect2
- SPATA45 | c.132G>A p.L44= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV60571542; called by muse, mutect2, varscan2
- SPEM2 | c.582G>A p.P194= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs774648377, COSV60366350; called by muse, mutect2, varscan2
- SPG7 | c.2211G>A p.E737= (on ENST00000268704; = p.E744= on NM_003119.4) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs1459461726, COSV51948622; called by muse, mutect2, varscan2
- SSH2 | c.3123G>A p.L1041= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV52168340; called by muse, mutect2, varscan2
- ST3GAL1 | c.123G>A p.Q41= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as rs763836994, COSV60611186; called by muse, mutect2, varscan2
- STK36 | c.3469C>T p.L1157= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV55325066; called by muse, mutect2
- STX11 | c.516C>T p.V172= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV62448741; called by muse, mutect2, varscan2
- SURF1 | c.609C>T p.L203= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs1564348081, COSV100034765; called by muse, mutect2
- SYNE2 | c.13728G>A p.K4576= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV59943631; called by muse, mutect2, varscan2
- SYT3 | c.699C>T p.L233= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs928925864, COSV58895881; called by muse, mutect2
- TECTA | c.4947G>A p.Q1649= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV50693322; called by muse, mutect2, varscan2
- THAP7 | c.555G>A p.Q185= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1259960350, COSV53146029, COSV53151647; called by muse, mutect2, varscan2
- TMEM145 | c.717G>A p.V239= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV56624277; called by muse, mutect2
- TMOD1 | c.567G>C p.R189= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV52245718; called by muse, mutect2, varscan2
- TNN | c.2277G>A p.Q759= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV53423218, COSV53424598; called by muse, mutect2, varscan2
- TRIM27 | c.1530G>A p.E510= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs777007090, COSV101019410; called by muse, mutect2, varscan2
- TTN | c.36135G>A p.V12045= (on ENST00000591111; = p.V4621= on NM_003319.4) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs759166253, COSV59943101; called by muse, mutect2, varscan2
- UNKL | c.171C>T p.F57= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1168576049, COSV57018976; called by muse, mutect2, varscan2
- UPF2 | c.2604C>T p.R868= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV62659152; called by muse, mutect2, varscan2
- USP8 | c.1845G>A p.R615= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1044306630, COSV56163140; called by muse, mutect2, varscan2
- ZBTB46 | c.921C>T p.F307= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs750939979, COSV55507826; called by muse, mutect2, varscan2
- ZFP57 | c.654C>T p.L218= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV65305863; called by muse, mutect2
- ZFYVE28 | c.210C>T p.I70= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52108780; called by muse, mutect2
- ZNF263 | c.439C>T p.L147= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV54595721, COSV54596495; called by muse, mutect2, varscan2
- ZNF28 | c.1308G>A p.E436= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV60422411; called by muse, mutect2, varscan2
- ZNF32 | c.669G>A p.R223= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV65641527; called by muse, mutect2, varscan2
- ZNF365 | c.21G>A p.E7= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV67925171; called by muse, mutect2, varscan2
- ZNF396 | c.243G>A p.L81= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV60473879; called by muse, mutect2, varscan2
- ZNF462 | c.5079G>A p.K1693= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs777400105, COSV52933215; called by muse, mutect2, varscan2
- ZNF564 | c.1428C>G p.P476= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs748397973, COSV59434573, COSV59436297; called by muse, mutect2, varscan2
- ZP2 | c.711C>T p.L237= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV54812933; called by muse, mutect2, varscan2
- BCAP29 | chr7:107621761 C>T | 3'Flank (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99143714; called by muse, mutect2, varscan2
- DALRD3 | chr3:49020178 G>A | 5'Flank (SNP) | VAF 21/37 reads (57%) | catalogued as COSV58244327; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22449G>A | Intron (SNP) | VAF 11/57 reads (19%) | catalogued as rs370874801; called by muse, mutect2, varscan2
- MAPK15 | c.780-134C>T | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as COSV62027682; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109866G>A | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs766045364, COSV58441856; called by muse, mutect2
- PRRX1 | c.599+3907G>A | Intron (SNP) | VAF 19/107 reads (18%) | catalogued as rs753113301, COSV53411991; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100157026 G>C | 3'Flank (SNP) | VAF 21/45 reads (47%) | catalogued as rs767933711; called by muse, mutect2, varscan2
- SEC14L2 | c.-1G>T | 5'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as COSV57240491; called by muse, mutect2, varscan2
